Somatic mutation profile of tumor specimen TCGA-B5-A5OE-01A (aliquot TCGA-B5-A5OE-01A-11D-A31U-09) from TCGA case TCGA-B5-A5OE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 68.2 years (24,905 days).
Specimen TCGA-B5-A5OE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc025a0-a58d-4f01-b25b-5fad5a56b4fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A5OE-10A (Blood Derived Normal), aliquot TCGA-B5-A5OE-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0df7c377-b1c3-417f-b7d5-3c8b5967601c

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS10 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs1156913215, COSV53882168; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ALKBH4 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); catalogued as COSV99479143; called by muse, mutect2, varscan2
- APEX2 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100895146; called by muse, mutect2, varscan2
- ATP2A1 | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100706809, COSV62870850, COSV62871192; called by muse, mutect2, varscan2
- ATP6V1C1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV101214832; called by muse, mutect2, varscan2
- CASP1 | c.1016C>T p.S339F (on ENST00000436863 / NM_033292.4; = p.S318F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99507141, COSV99507714; called by muse, mutect2, varscan2
- COL22A1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57359587, COSV57365604; called by muse, mutect2
- COL7A1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs147470888; called by muse, mutect2, varscan2
- CPAMD8 | c.2168C>T p.P723L (on ENST00000651564; = p.P676L on NM_015692.5) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs775789814, COSV52232882; called by muse, mutect2, varscan2
- DGKK | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs929307790, COSV101052877, COSV65709503; called by muse, mutect2, varscan2
- EDARADD | c.146C>G p.T49R (on ENST00000334232 / NM_145861.4; = p.T39R on NM_080738.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100512533; called by muse, mutect2, varscan2
- EXT2 | c.880del p.L294Ffs*38 (on ENST00000343631; = p.L327Ffs*38 on NM_000401.3) | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | catalogued as COSV59153689; called by mutect2, pindel
- FAM161A | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100281111; called by muse, mutect2, varscan2
- FBN1 | c.8284G>T p.A2762S | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100354000; called by muse, mutect2, varscan2
- GALNT13 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1173528879, COSV101222195; called by muse, mutect2, varscan2
- GRIA1 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV53603563; called by muse, mutect2, varscan2
- GUCA2A | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs182438227, COSV100812985, COSV100813023; called by muse, mutect2, varscan2
- IGSF1 | c.2869A>T p.S957C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100811825; called by muse, mutect2, varscan2
- JRK | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs373016139; called by muse, mutect2, varscan2
- KCNH5 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100525339, COSV59760970; called by muse, mutect2
- KIAA0319L | c.1183A>C p.N395H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356856; called by muse, mutect2
- KIF11 | c.2652G>A p.M884I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147512917, COSV99585631; called by muse, mutect2, varscan2
- KIT | c.1647+1G>T p.X549_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99853260; called by muse, mutect2, varscan2
- LCE1B | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as COSV100780254; called by muse, mutect2
- LRIG2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.365); catalogued as COSV63163735; called by muse, mutect2, varscan2
- MTHFD1L | c.747C>A p.S249R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV100943179; called by muse, mutect2, varscan2
- NEURL1 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV63507779; called by muse, mutect2, varscan2
- OR8D1 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100766531; called by muse, mutect2, varscan2
- OSMR | c.2030A>G p.K677R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99952646; called by muse, mutect2, varscan2
- PAG1 | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.734); catalogued as COSV99596982; called by muse, mutect2, varscan2
- PAGE4 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99489765; called by muse, mutect2, varscan2
- PCDH11X | c.3019G>A p.V1007I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs753325542, COSV53446116; called by muse, mutect2, varscan2
- PCDHGB2 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV99530572; called by muse, mutect2, varscan2
- PHF10 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1446877293, COSV100199742; called by muse, mutect2, varscan2
- POMGNT1 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | PolyPhen benign (0.063); catalogued as rs781102649, COSV100915365; called by muse, mutect2, varscan2
- PPFIA3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100494689, COSV61953832; called by muse, mutect2, varscan2
- PPP1R3A | c.1529A>G p.Y510C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99491943; called by muse, mutect2, varscan2
- RCC1 | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs764461802, COSV100868049; called by muse, mutect2, varscan2
- RELN | c.7668+1G>T p.X2556_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100632404; called by muse, mutect2, varscan2
- RSPO1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as COSV100740482; called by muse, mutect2
- SEMA3B | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100312703; called by muse, mutect2, varscan2
- SLC6A3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165739796, COSV54366298; called by muse, mutect2, varscan2
- SRRM2 | c.3706G>T p.E1236* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100070163; called by muse, mutect2, varscan2
- STRN4 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs377115014; called by muse, mutect2, varscan2
- SYCP1 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101050751; called by muse, mutect2
- TAB3 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.273); catalogued as COSV99915739; called by muse, mutect2, varscan2
- TUBD1 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs753772075, COSV56677059; called by muse, mutect2, varscan2
- ZBTB49 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs868668756, COSV61925663; called by mutect2, varscan2
- ZMAT1 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65659625; called by muse, mutect2
- FYCO1 | c.4337T>C p.L1446P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH3 | c.4640_4647+24del p.X1547_splice | Splice Site (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- PGBD1 | c.1381_1384del p.F461Vfs*5 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- TRPS1 | c.557del p.N186Tfs*10 (on ENST00000220888 / NM_001330599.2; = p.N199Tfs*10 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- DDX55 | c.1281A>G p.S427= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs1336717585, COSV99434168; called by muse, mutect2, varscan2
- ERBB2 | c.3357C>T p.P1119= | Silent (SNP) | VAF 36/52 reads (69%) | catalogued as COSV99506637; called by muse, mutect2, varscan2
- EXTL2 | c.421C>T p.L141= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100921080; called by muse, mutect2, varscan2
- EZHIP | c.888G>A p.A296= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs553854387, COSV57955188; called by muse, mutect2, varscan2
- KIAA0319L | c.1182G>T p.V394= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100356858; called by muse, mutect2
- LRP2 | c.10803C>T p.C3601= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as rs370876114; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.4464C>T p.S1488= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs189355247, COSV50078006; called by muse, mutect2, varscan2
- NIBAN1 | c.1815G>C p.L605= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1194440863, COSV100836228; called by muse, mutect2, varscan2
- OR10G2 | c.468C>T p.A156= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs190695639, COSV73390331; called by muse, mutect2, varscan2
- OR2L2 | c.201C>G p.L67= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as COSV100823115; called by muse, mutect2, varscan2
- POTEF | c.2397G>A p.E799= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV62545742; called by muse, mutect2, varscan2
- PXDNL | c.2589G>A p.A863= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV100681340; called by muse, mutect2, varscan2
- SHB | c.822A>G p.A274= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV100891041; called by muse, mutect2, varscan2
- SPICE1 | c.1401C>T p.S467= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs142804428; called by muse, mutect2, varscan2
- TBC1D23 | c.1494C>T p.S498= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs867931621, COSV61366787; called by muse, mutect2, varscan2
- TENT5D | c.252C>T p.D84= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs767118474, COSV57639931, COSV99075397; called by muse, mutect2, varscan2
- TFAP2E | c.975C>T p.A325= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs372241020; called by muse, mutect2, varscan2
- ZYG11B | c.426G>T p.V142= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FOLH1B | n.889A>G | RNA (SNP) | VAF 39/71 reads (55%) | catalogued as rs753908688; called by muse, mutect2, varscan2
- PNMA6A | chrX:153076544 G>A | 3'Flank (SNP) | VAF 21/31 reads (68%) | called by muse, mutect2, varscan2
- RAB4A | c.*1382A>G | 3'UTR (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100796975; called by muse, mutect2, varscan2
